CCDI case PBCCXB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/d3f10bca-aec3-457a-abce-97a6039684cf

Demographics
Sex at birth: female.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 17.4 years (6,342 days).

Biospecimens (3 samples)
- Sample 0DPZTA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZTJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZUB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
